Gene-level copy-number profile of tumor specimen TCGA-IP-7968-01A from TCGA case TCGA-IP-7968, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 74.2 years (27,114 days).
Specimen TCGA-IP-7968-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.ea4f316a-814f-4514-b424-0d282a0b096f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IP-7968-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/68018fac-d60f-40cd-a30c-5fc0c2606d6d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 126; copy number 1: 9,060; copy number 2: 45,932; copy number 3: 2,186; copy number 4: 756; copy number 5: 376; copy number 6: 518; copy number 7: 167; copy number 8: 271; copy number 9: 3; copy number 10: 272; copy number 11: 29; copy number 12: 25; copy number 14: 35; copy number 15: 24; copy number 17: 3; copy number 22: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IP-7968-01A-11D-2200-01): tumor purity 0.72, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 126 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–94,131,832, 13 genes: HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2.
- chr5:59,314,110–59,529,251, 2 genes: AC008833.1, NDUFB4P2.
- chr9:21,058,771–28,670,286, 107 genes (within-gene range 0–2) (broad region; genes not listed).
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,738 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:132,367,786–148,072,776, 210 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr4:149,934,376–151,015,727, 10 genes, copy number 6 (within-gene range 3–6): RNU6-1230P, AC105343.1, AC105343.2, DCLK2, RNU7-194P, LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1.
- chr4:152,536,264–163,093,628, 144 genes, copy number 6–10 (broad region; genes not listed).
- chr6:44,000,580–44,007,612, 1 gene, copy number 5: C6orf223.
- chr11:58,579,063–58,904,215, 11 genes, copy number 5 (within-gene range 1–5): ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2, TMA16P1, GLYATL2, GLYATL1P2.
- chr11:58,917,015–58,928,689, 1 gene, copy number 5: AP001652.1.
- chr11:85,336,075–88,428,176, 69 genes, copy number 7 (broad region; genes not listed).
- chr11:90,251,204–90,915,052, 1 gene, copy number 5 (within-gene range 2–5): DISC1FP1.
- chr11:90,555,774–103,479,863, 188 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:103,402,013–103,409,657, 7 genes, copy number 5: MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr12:21,354,959–23,251,499, 35 genes, copy number 6–12 (within-gene range 1–12): IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:24,212,421–25,250,936, 22 genes, copy number 11: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:26,121,991–26,299,290, 1 gene, copy number 5 (within-gene range 1–5): SSPN.
- chr12:26,139,249–32,646,050, 143 genes, copy number 5–14 (within-gene range 1–14) (broad region; genes not listed).
- chr15:88,636,153–88,875,353, 3 genes, copy number 17–22 (within-gene range 2–22): ISG20, AC103982.1, ACAN.
- chr15:90,529,923–90,883,458, 14 genes, copy number 22: CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585, BLM, SNORD18, AC124248.2, AC124248.1, RN7SL363P, FURIN.
- chr16:5,239,802–7,713,340, 1 gene, copy number 6 (within-gene range 1–17): RBFOX1.
- chr16:6,037,210–7,726,951, 14 genes, copy number 6–17: AC009135.2, AC009135.1, AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1.
- chr16:8,508,069–11,798,275, 94 genes, copy number 5 (broad region; genes not listed).
- chr16:14,071,319–14,266,773, 1 gene, copy number 7 (within-gene range 4–7): MRTFB.
- chr16:14,191,820–16,953,468, 93 genes, copy number 7 (broad region; genes not listed).
- chr16:24,472,798–33,991,551, 457 genes, copy number 6–15 (broad region; genes not listed).
- chr17:37,084,992–37,406,836, 1 gene, copy number 5 (within-gene range 2–5): ACACA.
- chr17:37,162,616–38,257,192, 29 genes, copy number 5 (within-gene range 3–5): AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA.
- chr17:39,057,019–41,786,931, 165 genes, copy number 10 (broad region; genes not listed).
- chr18:79,340,258–80,033,949, 23 genes, copy number 6: AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A.

Autosomal genes at a single copy (total copy number 1): 6,639. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
